Somatic mutation profile of tumor specimen 0DB97Y from CCDI case PBBKEG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 1.0 years (355 days).
Specimen 0DB97Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f789bad-588f-43ac-9863-5a21298656c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB97P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df9e7476-2480-4bb3-ab30-6551338a2977

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMD8 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 171/640 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1384757947, COSV100454821; called by muse, mutect2, varscan2
- SHTN1 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 52/2282 reads (2%) | catalogued as COSV53382220; called by muse, mutect2
- TRANK1 | c.7717C>T p.R2573W | Missense Mutation (SNP) | VAF 224/708 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs767126712, COSV57165302; called by muse, mutect2, varscan2
- UBN1 | c.2453C>T p.T818M | Missense Mutation (SNP) | VAF 141/492 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.715); catalogued as rs200733021; called by muse, mutect2, varscan2
- SEC14L1 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 286/1144 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 29/671 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- LAGE3 | c.39C>T p.D13= | Silent (SNP) | VAF 36/864 reads (4%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- ROPN1B | c.*18T>G | 3'UTR (SNP) | VAF 136/647 reads (21%) | called by muse, mutect2, varscan2
